TCGA case TCGA-W5-AA2Q — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f47dbd99-920b-4b39-a1b0-6c152ad24884

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 68.6 years (25,069 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 50 days; Child pugh classification: A; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 50 days; Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 247 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 55.
- Platelets 174 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Prothrombin Time 9.3 Seconds [Blood test normal range lower: 8.4; Blood test normal range upper: 12].
- Total Bilirubin 1.4 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Creatinine 1 mg/dL [Blood test normal range lower: 0.9; Blood test normal range upper: 1.4].
- Albumin 3.7 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.4; Blood test normal range upper: 4.7].
- Alpha Fetoprotein 4.3 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Tobacco, Smoking.
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 165 cm; BMI: 24.6.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Bone Cancer.
- Relatives with cancer history count: 1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA2Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-W5-AA2Q-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 33; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-W5-AA2Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W5-AA2Q-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-W5-AA2Q-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-W5-AA2Q-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Extended Lobectomy.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 50 days; disease-specific survival: no event (censored), 50 days; disease-free interval: no event (censored), 50 days; progression-free interval: no event (censored), 50 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W5-AA2Q-01A-11D-A416-01): tumor purity 0.91, ploidy 2.29, whole-genome doublings 0.
